Somatic mutation profile of tumor specimen 0DUNP6 from CCDI case PBCLBI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Optic nerve; Age at diagnosis: 14.7 years (5,368 days).
Specimen 0DUNP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee6f0fb8-2b16-4795-8a39-a702b501b354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNOZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad598fc-2924-41f9-9ef4-46a11c17db1b

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 197/777 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYO9A | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs770090394; called by muse, mutect2, varscan2
- PRG4 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs779434500, COSV63356598; called by muse, mutect2, varscan2
- WNK1 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 128/331 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs759393178, COSV100267487; called by muse, mutect2, varscan2
- NEDD1 | c.1486T>G p.S496A | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCSK5 | c.1900+91T>C | Intron (SNP) | VAF 54/236 reads (23%) | catalogued as rs62556589, COSV65082969; called by muse, varscan2
